CCDI case PBCIMG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e9d0c8a5-3727-4322-adc2-8fe5a36d9eef

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (791 days).

Biospecimens (3 samples)
- Sample 0DSP24: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSP2F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSP2L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
